Somatic mutation profile of tumor specimen TCGA-XX-A899-01A (aliquot TCGA-XX-A899-01A-11D-A36J-09) from TCGA case TCGA-XX-A899, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 46.6 years (17,022 days).
Specimen TCGA-XX-A899-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 579a3ebc-d38d-4029-a05c-d3e8ea2549d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XX-A899-10A (Blood Derived Normal), aliquot TCGA-XX-A899-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/218cbd80-c866-48b9-90d6-d0a5210fd96d

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 22, Silent 9, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.1531C>T p.Q511* | Nonsense Mutation (SNP) | VAF 19/90 reads (21%) | catalogued as rs1131690810, COSV55734715; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.248T>C p.F83S | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs1560137208, COSV55924440, COSV55950009; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC134980.2 | c.689C>G p.S230C | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV100171508; called by muse, mutect2, varscan2
- ATP6V1D | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.51); catalogued as rs1441024453, COSV99370761; called by muse, mutect2, varscan2
- CLDN1 | c.97T>C p.Y33H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV99790524; called by muse, mutect2, varscan2
- COG1 | c.2057G>A p.S686N | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV100245211; called by muse, mutect2
- DCK | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV99709141; called by muse, mutect2, varscan2
- FAM135A | c.1148C>T p.S383F (on ENST00000370479 / NM_001351599.1; = p.S366F on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52058570; called by muse, mutect2, varscan2
- FAM81A | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1406302088, COSV55678307; called by muse, mutect2
- GAS2L1 | c.935A>G p.E312G | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.715); catalogued as COSV99329433; called by muse, mutect2, varscan2
- KDM2A | c.2089G>A p.V697M | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV100445428; called by muse, mutect2, varscan2
- KLRC2 | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV101122671, COSV67899690; called by muse, mutect2, varscan2
- MAPK15 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.199); catalogued as COSV100567746; called by muse, mutect2, varscan2
- MARK2 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs199684279; called by mutect2, varscan2
- MEGF8 | c.5204C>G p.S1735* (on ENST00000251268 / NM_001271938.2; = p.S1668* on NM_001410.3) | Nonsense Mutation (SNP) | VAF 9/92 reads (10%) | catalogued as COSV99234992; called by muse, mutect2, varscan2
- NCKAP5 | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.382); catalogued as COSV100490649; called by muse, varscan2
- OR4D2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs142058863, COSV101613850; called by muse, mutect2, varscan2
- SOCS4 | c.1245G>A p.M415I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV100216081; called by muse, mutect2
- SRRM2 | c.8024C>T p.S2675F | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99241308; called by muse, mutect2
- TCTN1 | c.820A>T p.R274W | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV100885911; called by muse, mutect2, varscan2
- TMEM123 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 206/282 reads (73%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs748630464, COSV100772234; called by muse, varscan2
- TMEM123 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 112/167 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100772235; called by muse, varscan2
- TNXB | c.3660G>C p.E1220D (on ENST00000647633; = p.E973D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.535); catalogued as COSV100926028; called by muse, mutect2, varscan2
- TBX3 | c.490_494del p.K164Sfs*10 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- TRAV8-1 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- BMP15 | c.21T>C p.L7= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs1291665414, COSV99399264; called by muse, mutect2, varscan2
- C2CD3 | c.4080G>A p.V1360= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV100486343; called by muse, mutect2
- IKBKE | c.285G>A p.L95= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100898121, COSV100898272; called by muse, mutect2, varscan2
- ISYNA1 | c.726C>T p.N242= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs766323136, COSV54211421; called by muse, varscan2
- LRRC8E | c.993C>G p.L331= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs1279714091, COSV100142701; called by muse, mutect2
- NXF3 | c.1413C>T p.F471= | Silent (SNP) | VAF 26/298 reads (9%) | catalogued as COSV101221898; called by muse, mutect2
- TXNDC2 | c.1107C>A p.P369= (on ENST00000306084 / NM_001098529.2; = p.P302= on NM_032243.6) | Silent (SNP) | VAF 27/172 reads (16%) | catalogued as rs1299690585, COSV100045870, COSV60156483; called by muse, mutect2, varscan2
- ZNF44 | c.636T>G p.T212= (on ENST00000356109 / NM_001164276.2; = p.T164= on NM_016264.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100633501; called by muse, mutect2, varscan2
- ZNFX1 | c.2475C>T p.I825= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs764181784, COSV65579217; called by mutect2, varscan2
